Somatic mutation profile of tumor specimen 0DIMX0 from CCDI case PBBVNR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Desmoplastic small round cell tumor; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 14.2 years (5,169 days).
Specimen 0DIMX0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3336ba4-1f12-40b0-84d7-fa9210b80278.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIMWN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a5f85aa-7082-4f60-961c-43ab90217eaa

The open-access MAF lists 22 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, Intron 2, 5'UTR 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ELP1 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 62/1398 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs367552387, COSV101010406; called by muse, mutect2
- HEBP1 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 370/671 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs76698360; called by muse, mutect2, varscan2
- MECR | c.13A>G p.S5G | Missense Mutation (SNP) | VAF 173/337 reads (51%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); catalogued as rs1005176880; called by muse, mutect2, varscan2
- OR8J3 | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 362/600 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1258941149; called by muse, mutect2, varscan2
- PFKL | c.529G>A p.G177S | Missense Mutation (SNP) | VAF 46/774 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs529148263; called by muse, mutect2
- RPL15 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 42/482 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as rs749541129, COSV100323311; called by muse, mutect2
- SYNE2 | c.10588C>G p.L3530V | Missense Mutation (SNP) | VAF 344/585 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs553625015; called by muse, mutect2, varscan2
- ADAM7 | c.250A>C p.N84H | Missense Mutation (SNP) | VAF 159/579 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 35/1196 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- HFM1 | c.1676A>T p.Q559L | Missense Mutation (SNP) | VAF 32/880 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.093); called by muse, mutect2
- KHDRBS2 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 320/748 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- MEGF9 | c.275C>A p.A92D | Missense Mutation (SNP) | VAF 191/414 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- ABI3 | c.147G>A p.E49= | Silent (SNP) | VAF 40/780 reads (5%) | called by muse, mutect2
- OR6M1 | c.450C>A p.A150= | Silent (SNP) | VAF 20/318 reads (6%) | called by muse, mutect2
- PRNP | c.126C>A p.G42= | Silent (SNP) | VAF 289/605 reads (48%) | called by muse, mutect2, varscan2
- SH3BP2 | c.786G>A p.R262= | Silent (SNP) | VAF 28/490 reads (6%) | called by muse, mutect2
- SLC26A7 | c.1200G>A p.L400= | Silent (SNP) | VAF 32/536 reads (6%) | catalogued as rs1167540771; called by muse, mutect2
- ADAMTS5 | c.-18C>T | 5'UTR (SNP) | VAF 40/636 reads (6%) | called by muse, mutect2
- CYLD | c.*81G>A | 3'UTR (SNP) | VAF 6/100 reads (6%) | catalogued as rs1275758699; called by muse, mutect2
- DUOX2 | c.3006-19C>A | Intron (SNP) | VAF 163/330 reads (49%) | called by muse, mutect2, varscan2
- MRPS36 | c.-46C>A | 5'UTR (SNP) | VAF 146/381 reads (38%) | catalogued as rs368315229; called by muse, mutect2, varscan2
- VWA3B | c.3157+58C>A | Intron (SNP) | VAF 20/347 reads (6%) | called by muse, mutect2
